Somatic mutation profile of tumor specimen ALCH-AEUU-TTP1-A (aliquot ALCH-AEUU-TTP1-A-2-0-D-A667-36) from ALCHEMIST case ALCH-AEUU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,160 days).
Specimen ALCH-AEUU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57844c23-bc03-4102-811a-b27b0355f97c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEUU-NB1-A (Blood Derived Normal), aliquot ALCH-AEUU-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8959a602-694e-4b17-ad1e-6d3e2a897f2f

The open-access MAF lists 179 somatic variants for this specimen: 122 protein-altering or splice-affecting, 43 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 43, Nonsense Mutation 7, RNA 6, Intron 5, Splice Site 2, 3'UTR 1, 5'Flank 1, Frame Shift Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 50/487 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ASS1 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV61690271; called by muse, mutect2, varscan2
- CFAP54 | c.8687G>A p.R2896H | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.535); catalogued as rs1045099175; called by muse, mutect2
- CTNNB1 | c.998A>T p.Y333F | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV62693301; called by muse, mutect2
- DCAF8L1 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV71595288; called by muse, mutect2
- DIAPH1 | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 18/606 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99526503; called by muse, mutect2
- DNMT3L | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54266476; called by muse, mutect2, varscan2
- ELP2 | c.1913G>T p.W638L | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV100626797; called by muse, mutect2
- FLT3 | c.2461C>G p.H821D | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99609567; called by muse, mutect2
- FSD1L | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 86/846 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs933791489; called by muse, mutect2
- GRM5 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59589578; called by muse, mutect2
- INTS1 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV67179331; called by muse, mutect2
- KCNIP1 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV66184268; called by muse, mutect2, varscan2
- KIR2DL1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.476); catalogued as rs779325970; called by muse, mutect2, varscan2
- LRP1B | c.13253C>T p.S4418F | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.726); catalogued as rs1366808778, COSV101252176; called by muse, mutect2
- MED13 | c.3447A>G p.I1149M | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV101181573; called by muse, mutect2
- MUC21 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV100888863; called by muse, mutect2, varscan2
- MYH2 | c.2698-1G>T p.X900_splice | Splice Site (SNP) | VAF 24/468 reads (5%) | catalogued as COSV99821060; called by muse, mutect2
- MYL4 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs1323974515; called by muse, mutect2
- MYOM1 | c.1778G>C p.G593A | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV55291098; called by muse, mutect2
- NLRP3 | c.1853A>T p.K618M | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV100275847; called by muse, mutect2
- OR1F1 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs756623758; called by muse, mutect2
- PDE6B | c.1621G>T p.V541L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV55325393; called by muse, mutect2
- PDHA1 | c.57G>C p.P19= | Splice Region (SNP) | VAF 11/148 reads (7%) | catalogued as COSV63329015; called by muse, mutect2
- PIK3C2A | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99790111; called by muse, mutect2
- POU3F4 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM005402; called by muse, mutect2
- PPP2R1B | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 30/593 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV99064492; called by muse, mutect2
- RAPGEF1 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as rs1241986147; called by muse, mutect2
- REST | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1300652443; called by muse, mutect2, varscan2
- RYR2 | c.8618C>A p.P2873H | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63720136; called by muse, mutect2
- SLC5A7 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV50889563; called by muse, mutect2
- TMEM176A | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50241304; called by muse, mutect2
- TPTE2 | c.1289T>G p.L430* (on ENST00000400230 / NM_199254.2; = p.L353* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 28/302 reads (9%) | catalogued as COSV55019423; called by muse, mutect2
- TRPM6 | c.4481C>A p.A1494D | Missense Mutation (SNP) | VAF 50/573 reads (9%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); catalogued as COSV100665440, COSV62511228; called by muse, mutect2
- WDR87 | c.5104C>A p.Q1702K | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.413); catalogued as COSV58199940; called by muse, mutect2, varscan2
- ABCA13 | c.9991A>T p.I3331F | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA3 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ADAMTS14 | c.1145G>T p.C382F | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADGRE2 | c.1848G>T p.W616C | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR1B10 | c.352-1G>T p.X118_splice | Splice Site (SNP) | VAF 14/368 reads (4%) | called by muse, mutect2
- AMY2A | c.663C>A p.D221E | Missense Mutation (SNP) | VAF 37/842 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- ANK2 | c.5363C>T p.P1788L | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ANKRD60 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- APEX2 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ASXL3 | c.5444T>C p.L1815P | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2
- BBOX1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- BTG4 | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- C10orf90 | c.192A>T p.R64S | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- C1orf43 | c.386G>T p.G129V (on ENST00000368521 / NM_001297718.2; = p.G95V on NM_015449.4) | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CCDC168 | c.17757G>T p.K5919N | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CDADC1 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); called by muse, mutect2
- CEP350 | c.8752C>G p.H2918D | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CMYA5 | c.5972C>T p.P1991L | Missense Mutation (SNP) | VAF 27/491 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); called by muse, mutect2
- CNKSR2 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- CNTN4 | c.3039C>G p.I1013M | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- DAGLA | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- DCUN1D5 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- DLG2 | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DMBT1 | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK10 | c.2883G>T p.R961S | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2
- EYA1 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 68/674 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- EYS | c.3833C>A p.A1278D | Missense Mutation (SNP) | VAF 36/401 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2
- EYS | c.2762C>A p.S921Y | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FAM71B | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- FGD6 | c.3191G>T p.G1064V | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.12129T>A p.S4043R | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2
- GPR158 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 44/509 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GPR182 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- GRIK5 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- GRIPAP1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAUS1 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- HS2ST1 | c.319A>T p.I107F | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- INTS1 | c.554G>C p.C185S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by mutect2, varscan2
- INTS13 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 29/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- IQSEC2 | c.2639C>A p.T880N (on ENST00000642864 / NM_001111125.3; = p.T675N on NM_015075.2) | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNH1 | c.2023G>T p.D675Y (on ENST00000271751 / NM_172362.3; = p.D648Y on NM_002238.4) | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- KIR2DL1 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, varscan2
- KIZ | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- LAMC3 | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LGR4 | c.2213C>A p.S738* | Nonsense Mutation (SNP) | VAF 30/293 reads (10%) | called by muse, mutect2, varscan2
- LOXHD1 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRIT3 | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- MACF1 | c.11345C>T p.A3782V (on ENST00000372915; = p.A1715V on NM_012090.5) | Missense Mutation (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- MAP3K15 | c.3938C>A p.A1313D | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2
- MGA | c.2944G>T p.G982* | Nonsense Mutation (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- MPDZ | c.5131G>T p.D1711Y | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MPP1 | c.535T>G p.C179G | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTMR1 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MYH1 | c.4811C>A p.T1604K | Missense Mutation (SNP) | VAF 53/502 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO5B | c.1750A>T p.K584* | Nonsense Mutation (SNP) | VAF 17/433 reads (4%) | called by muse, mutect2
- NDUFB9 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR2T1 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PAX4 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB11 | c.1462T>A p.Y488N | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PROX1 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRTG | c.3081_3084del p.F1027Lfs*9 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | called by mutect2, pindel
- RBM10 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- SCARF1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- SCN5A | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SIPA1L2 | c.2629T>A p.S877T | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC17A7 | c.933C>A p.N311K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SLC26A5 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 27/325 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2
- SLC35A2 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SLC35A2 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC35A2 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SLC4A7 | c.1172A>T p.K391I | Missense Mutation (SNP) | VAF 27/315 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2
- SLC7A3 | c.345G>T p.W115C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- SLIT3 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPAG6 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- STAG2 | c.797T>A p.L266H | Missense Mutation (SNP) | VAF 27/560 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, mutect2
- SYT4 | c.590C>A p.T197K | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.396); called by muse, mutect2
- TFAP2B | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.119); called by muse, mutect2
- TOGARAM2 | c.1736A>C p.Q579P | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- TRIM32 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRIM48 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- TRPC4 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2
- TSFM | c.665G>T p.R222L (on ENST00000323833 / NM_001172696.2; = p.R201L on NM_005726.6) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5B | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDHD1 | c.2571C>G p.F857L | Missense Mutation (SNP) | VAF 26/489 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- ZEB2 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 63/686 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ZNF354B | c.1671A>T p.K557N | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF574 | c.2291G>C p.R764P | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRL3 | c.4417C>T p.L1473= (on ENST00000506720 / NM_001322402.2; = p.L1362= on NM_015236.6) | Silent (SNP) | VAF 20/412 reads (5%) | called by muse, mutect2
- AMER1 | c.2589C>T p.P863= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- ASTN1 | c.2016G>T p.P672= | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as COSV56066950, COSV56082392; called by muse, mutect2
- BRWD3 | c.2184G>T p.A728= | Silent (SNP) | VAF 36/422 reads (9%) | called by muse, mutect2
- CCDC146 | c.2640C>T p.A880= | Silent (SNP) | VAF 22/179 reads (12%) | catalogued as rs760592292; called by muse, mutect2, varscan2
- CHD6 | c.5517A>T p.S1839= | Silent (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- CRB3 | c.235T>C p.L79= | Silent (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- CTAGE1 | c.333T>A p.L111= | Silent (SNP) | VAF 50/628 reads (8%) | called by muse, mutect2
- CWH43 | c.1998T>A p.S666= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV56938052; called by muse, varscan2
- CYFIP2 | c.9G>T p.T3= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.837G>T p.A279= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV64421649, COSV64422961; called by muse, mutect2
- GDAP1 | c.909A>T p.A303= | Silent (SNP) | VAF 24/584 reads (4%) | called by muse, mutect2
- HYDIN | c.5664G>T p.L1888= | Silent (SNP) | VAF 17/371 reads (5%) | called by muse, mutect2
- INTS6L | c.618C>T p.R206= | Silent (SNP) | VAF 62/682 reads (9%) | catalogued as rs781853258; called by muse, mutect2
- ITGA8 | c.2562C>A p.L854= | Silent (SNP) | VAF 24/340 reads (7%) | catalogued as COSV65234403; called by muse, mutect2
- LAMC3 | c.951C>A p.T317= | Silent (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- LRRC4C | c.1204C>A p.R402= | Silent (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- MTUS2 | c.1116G>C p.G372= | Silent (SNP) | VAF 19/216 reads (9%) | catalogued as COSV70914563; called by muse, mutect2
- MYOF | c.21A>G p.E7= | Silent (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- NFASC | c.2685C>A p.R895= (on ENST00000339876 / NM_001378329.1; = p.R998= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- NHSL2 | c.927T>A p.S309= (on ENST00000510661; = p.S675= on NM_001013627.2) | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- NIPA1 | c.288C>T p.T96= | Silent (SNP) | VAF 32/407 reads (8%) | called by muse, mutect2
- OR10A5 | c.723G>C p.T241= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV55054593; called by muse, mutect2
- OR2L13 | c.825C>A p.V275= | Silent (SNP) | VAF 38/444 reads (9%) | catalogued as COSV100813880; called by muse, mutect2
- OR2T11 | c.192C>A p.S64= | Silent (SNP) | VAF 22/325 reads (7%) | catalogued as rs1344332879; called by muse, mutect2
- PAGE3 | c.72A>T p.V24= | Silent (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
- PAPPA2 | c.5238C>T p.N1746= | Silent (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- PGAP1 | c.1011A>T p.P337= | Silent (SNP) | VAF 13/310 reads (4%) | called by muse, mutect2
- POM121L2 | c.3039C>T p.G1013= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs768139368, COSV66277577; called by muse, mutect2, varscan2
- PPP1R21 | c.225A>C p.L75= | Silent (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- PRPS2 | c.924C>A p.S308= | Silent (SNP) | VAF 32/381 reads (8%) | catalogued as COSV101037780, COSV66179807; called by muse, mutect2
- PTPRC | c.1656T>C p.F552= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as COSV61409322; called by muse, mutect2
- SCN5A | c.420C>A p.T140= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV61135738; called by muse, mutect2, varscan2
- SRPX2 | c.318G>T p.L106= | Silent (SNP) | VAF 37/329 reads (11%) | called by muse, mutect2, varscan2
- STK31 | c.2949A>G p.P983= | Silent (SNP) | VAF 52/572 reads (9%) | catalogued as rs1205103428; called by muse, mutect2
- TCEA2 | c.546C>T p.D182= | Silent (SNP) | VAF 18/76 reads (24%) | called by mutect2, varscan2
- TRIM4 | c.1350G>T p.L450= | Silent (SNP) | VAF 21/206 reads (10%) | called by muse, mutect2, varscan2
- TRPC5 | c.1197C>A p.P399= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV99461636; called by muse, mutect2
- UBASH3A | c.1149T>A p.L383= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- UBQLNL | c.339C>T p.F113= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs1265542643, COSV100974238; called by muse, mutect2
- UHRF1 | c.660C>T p.G220= (on ENST00000612630 / NM_001290050.1; = p.G233= on NM_013282.4) | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- USP26 | c.2097G>A p.K699= | Silent (SNP) | VAF 30/319 reads (9%) | called by muse, mutect2
- VANGL2 | c.312C>A p.S104= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- AC024940.1 | n.3378G>A | RNA (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- AC139769.1 | n.214-4159G>T | Intron (SNP) | VAF 16/380 reads (4%) | called by muse, mutect2
- C8orf31 | n.584G>T | RNA (SNP) | VAF 12/53 reads (23%) | catalogued as rs137944456; called by muse, mutect2, varscan2
- CCNYL2 | n.624-2646G>T | Intron (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- KIR2DP1 | n.980A>T | RNA (SNP) | VAF 11/319 reads (3%) | called by muse, mutect2
- MIR518A2 | n.12G>T | RNA (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- MSL3P1 | n.739T>A | RNA (SNP) | VAF 33/248 reads (13%) | called by muse, mutect2, varscan2
- OR7A2P | n.278C>A | RNA (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- PCDHA3 | c.2394+1449C>A | Intron (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- POTEC | c.1126+1548C>G | Intron (SNP) | VAF 41/276 reads (15%) | called by muse, mutect2, varscan2
- RNU6-104P | chr8:43300551 G>A | 5'Flank (SNP) | VAF 22/293 reads (8%) | called by muse, mutect2
- SRP19 | c.*1436T>C | 3'UTR (SNP) | VAF 8/55 reads (15%) | catalogued as rs761988975; called by muse, mutect2, varscan2
- TBXAS1 | c.333+1856C>G | Intron (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- XIAP | c.-269G>T | 5'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
